Somatic mutation profile of tumor specimen TCGA-AY-A71X-01A (aliquot TCGA-AY-A71X-01A-12D-A36X-10) from TCGA case TCGA-AY-A71X, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 54.5 years (19,904 days).
Specimen TCGA-AY-A71X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41554674-a00a-48f6-a776-22d4c8ac2c32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-A71X-10A (Blood Derived Normal), aliquot TCGA-AY-A71X-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1785b9cd-efe3-4447-bb1b-89acde345b8e

The open-access MAF lists 93 somatic variants for this specimen: 75 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 16, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 2, 3'UTR 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ10 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 52/128 reads (41%) | catalogued as rs138943405; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 129/239 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM11 | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762803709, COSV52346276; called by muse, mutect2, varscan2
- ADGRA1 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141186395; called by muse, mutect2, varscan2
- ANXA1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974008; called by muse, mutect2, varscan2
- APBA3 | c.1525C>T p.L509F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99516320; called by muse, mutect2, varscan2
- ARSF | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100839522; called by muse, mutect2, varscan2
- CCAR1 | c.397C>G p.P133A | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99771226; called by muse, mutect2, varscan2
- CCER1 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727102; called by muse, varscan2
- CDH23 | c.7087G>A p.E2363K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753690054, COSV56450872; ClinVar: uncertain significance; called by muse, mutect2
- CEACAM3 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV55761872; called by muse, mutect2, varscan2
- CEP170B | c.1373G>A p.R458H (on ENST00000453495; = p.R387H on NM_015005.3) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.52); catalogued as rs1446936416; called by muse, mutect2
- CNTN5 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99677387, COSV99679149; called by muse, mutect2, varscan2
- COL21A1 | c.1029G>A p.T343= | Splice Region (SNP) | VAF 42/100 reads (42%) | catalogued as rs373532211; called by muse, mutect2, varscan2
- CORIN | c.3079G>A p.V1027I | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs758207729, COSV99904040; called by muse, mutect2, varscan2
- CR1 | c.3707C>T p.A1236V | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs539603642, COSV65458940; called by muse, mutect2
- CREB3 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1264130901, COSV59208277; called by muse, mutect2, varscan2
- CTDSP1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1476365869, COSV99812041; called by muse, mutect2
- DALRD3 | c.1511G>A p.G504E (on ENST00000341949 / NM_001009996.3; = p.G337E on NM_018114.5) | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100482867; called by muse, mutect2, varscan2
- DGKG | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99403870; called by muse, mutect2, varscan2
- DLG3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as COSV99529850; called by muse, mutect2, varscan2
- DNAH5 | c.6556C>T p.R2186W | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756444637, COSV99451864; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778632004, COSV62568296; called by muse, mutect2, varscan2
- EIF3A | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs375388729; called by muse, mutect2, varscan2
- EML1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs746895186, COSV51753694; called by muse, mutect2, varscan2
- FBXO5 | c.329C>G p.T110S | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57670544, COSV57671829, COSV99999891; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2022G>T p.L674F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV100437307; called by muse, mutect2, varscan2
- GALNT9 | c.1685G>A p.R562Q (on ENST00000328957 / NM_001122636.2; = p.R196Q on NM_021808.3) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs374716980, COSV61098709; called by muse, mutect2, varscan2
- GAS2L3 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs985464909, COSV99902988; called by muse, mutect2, varscan2
- GNB4 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs864622729, COSV99224402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GORASP2 | c.397A>G p.S133G | Missense Mutation (SNP) | VAF 221/479 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV52202156; called by muse, mutect2, varscan2
- HTT | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs747431001, COSV100751018; called by muse, mutect2, varscan2
- IQSEC3 | c.952G>A p.A318T (on ENST00000538872 / NM_001170738.2; = p.A15T on NM_015232.1) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1170799147, COSV58283080; called by muse, mutect2, varscan2
- KIAA0319L | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs201085308, COSV100357528; called by muse, mutect2, varscan2
- KIR3DL1 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as rs779085160, COSV58491884; called by muse, mutect2, varscan2
- KPNA6 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1269464403, COSV65360414; called by muse, mutect2, varscan2
- LRFN3 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777683616, COSV99873477; called by muse, varscan2
- MROH9 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100882872; called by muse, mutect2, varscan2
- MYO5A | c.3168G>T p.M1056I | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100697896; called by muse, mutect2
- NAALADL1 | c.2174C>A p.T725K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV100101261; called by muse, mutect2, varscan2
- NET1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs776534266, COSV61791214; called by muse, mutect2, varscan2
- NLGN3 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as COSV62442357; called by muse, mutect2, varscan2
- NR0B1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66764182; called by muse, mutect2, varscan2
- NUMA1 | c.1131A>C p.E377D | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100706392, COSV61183103; called by muse, mutect2, varscan2
- OLFM1 | c.1420G>A p.V474M (on ENST00000371793 / NM_001282611.2; = p.V456M on NM_014279.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53277759; called by muse, mutect2, varscan2
- PCDHA13 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs1554181316, COSV56558219; called by muse, mutect2, varscan2
- PLD2 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV99562530; called by muse, mutect2, varscan2
- SATB2 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 60/130 reads (46%) | catalogued as COSV99611907; called by muse, mutect2, varscan2
- SDK2 | c.3808G>A p.V1270M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1025216163; called by muse, mutect2, varscan2
- SFXN5 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); catalogued as rs756281703, COSV55586653; called by muse, mutect2, varscan2
- SLC9A3 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138480019; called by muse, varscan2
- SLIT2 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV56564836; called by muse, mutect2, varscan2
- SPACA7 | c.241+1G>A p.X81_splice | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as rs765107270, COSV52102476; called by muse, mutect2, varscan2
- STARD8 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV52923118; called by muse, mutect2, varscan2
- TECPR2 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs758522721, COSV63972976; called by muse, mutect2
- TESC | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762965516, COSV100069441; called by muse, mutect2, varscan2
- TMEM63B | c.2131A>G p.M711V | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs752303826, COSV99441848; called by muse, mutect2, varscan2
- TNS2 | c.1087G>A p.D363N (on ENST00000314250 / NM_170754.4; = p.D373N on NM_015319.2) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs140911911; called by muse, mutect2, varscan2
- TRPC3 | c.571G>A p.V191I (on ENST00000379645 / NM_001366479.2; = p.V118I on NM_003305.2) | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53374304; called by muse, mutect2, varscan2
- TTN | c.93880G>A p.E31294K (on ENST00000591111; = p.E23870K on NM_003319.4) | Missense Mutation (SNP) | VAF 86/119 reads (72%) | PolyPhen possibly damaging (0.668); catalogued as rs1407053984, COSV59876323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.14599A>C p.T4867P (on ENST00000591111; = p.T3940P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/111 reads (71%) | PolyPhen benign (0.006); catalogued as COSV100621287, COSV59870239; called by muse, mutect2, varscan2
- TTN | c.10235G>T p.G3412V (on ENST00000591111; = p.G3366V on NM_003319.4) | Missense Mutation (SNP) | VAF 123/153 reads (80%) | PolyPhen probably damaging (1); catalogued as COSV100621289, COSV60303237; called by muse, mutect2, varscan2
- USP32 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749641360, COSV100342435; called by muse, mutect2, varscan2
- VIP | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV100923951; called by muse, mutect2
- WDR6 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.611); catalogued as COSV59087461; called by muse, varscan2
- ZNF609 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs910808816, COSV100441436; called by muse, mutect2, varscan2
- ZNF615 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV100943889; called by muse, mutect2, varscan2
- APC | c.4338_4344del p.Q1447Sfs*24 | Frame Shift Del (DEL) | VAF 33/46 reads (72%) | called by mutect2, varscan2
- IGLV7-43 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- KMT2C | c.8445dup p.S2816Ifs*6 | Frame Shift Ins (INS) | VAF 128/317 reads (40%) | called by mutect2, varscan2
- RGMB | c.237_238del p.E80Vfs*34 (on ENST00000513185 / NM_001366508.1; = p.E121Vfs*34 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 49/79 reads (62%) | called by mutect2, pindel, varscan2
- SEMA5B | c.125-1_133del p.X42_splice | Splice Site (DEL) | VAF 50/184 reads (27%) | called by mutect2, pindel, varscan2
- TNRC6B | c.4053_4059dup p.A1354Tfs*46 (on ENST00000454349 / NM_001162501.2; = p.A1244Tfs*46 on NM_015088.3) | Frame Shift Ins (INS) | VAF 30/68 reads (44%) | called by mutect2, varscan2
- TOP1 | c.1356dup p.C453Mfs*40 | Frame Shift Ins (INS) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- TPGS1 | c.15_56del p.E5_T18del | In Frame Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel
- CCT8L2 | c.585C>T p.D195= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as rs745781591, COSV63461750; called by muse, mutect2, varscan2
- CYP11A1 | c.339C>T p.S113= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs761284043, COSV51432022; called by muse, mutect2, varscan2
- DOK5 | c.459C>T p.G153= | Silent (SNP) | VAF 66/172 reads (38%) | catalogued as rs762067549, COSV52817571; called by muse, mutect2, varscan2
- DUOX2 | c.2373C>T p.P791= | Silent (SNP) | VAF 67/151 reads (44%) | catalogued as COSV66534296; called by muse, mutect2, varscan2
- FBXO17 | c.504G>A p.G168= | Silent (SNP) | VAF 56/127 reads (44%) | catalogued as COSV53070028; called by muse, mutect2, varscan2
- FXR2 | c.1653C>T p.R551= | Silent (SNP) | VAF 64/136 reads (47%) | catalogued as COSV100002144; called by muse, mutect2, varscan2
- LMLN | c.1569C>T p.S523= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as rs1449907812; called by muse, mutect2
- MAST3 | c.2247C>T p.D749= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV99445819; called by muse, mutect2, varscan2
- PIK3CB | c.1080T>C p.G360= | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as COSV100005885; called by muse, mutect2, varscan2
- PRAMEF20 | c.606C>G p.V202= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- SARDH | c.1608C>T p.Y536= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs1253163664, COSV64101569; called by muse, mutect2, varscan2
- THBS2 | c.123C>T p.G41= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs760926840, COSV64679856; called by muse, mutect2, varscan2
- TNXB | c.9819G>T p.G3273= (on ENST00000647633; = p.G3026= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as COSV100926459; called by muse, mutect2, varscan2
- TTI2 | c.355C>T p.L119= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV62452370; called by muse, mutect2, varscan2
- VCAM1 | c.216G>A p.T72= | Silent (SNP) | VAF 92/218 reads (42%) | catalogued as COSV54118851; called by muse, mutect2, varscan2
- ZNF821 | c.381C>T p.C127= (on ENST00000425432 / NM_001376297.1; = p.C85= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as rs189263731, COSV100546832; called by muse, mutect2, varscan2
- TMEM105 | n.844G>A | RNA (SNP) | VAF 50/134 reads (37%) | catalogued as COSV100129678; called by muse, mutect2, varscan2
- UVSSA | c.*8895C>T | 3'UTR (SNP) | VAF 19/97 reads (20%) | catalogued as rs144681251; called by muse, varscan2
